Somatic mutation profile of tumor specimen TCGA-22-1012-01A (aliquot TCGA-22-1012-01A-01W-0782-08) from TCGA case TCGA-22-1012, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 80.1 years (29,273 days).
Specimen TCGA-22-1012-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efa6108e-171a-43ec-971b-e08d4f6d85dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-1012-11A (Solid Tissue Normal), aliquot TCGA-22-1012-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3a53e23-4452-4be2-8b1d-0db79288534f

The open-access MAF lists 288 somatic variants for this specimen: 213 protein-altering or splice-affecting, 58 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 58, Nonsense Mutation 20, Intron 10, Frame Shift Del 10, Splice Site 7, RNA 4, Splice Region 2, Frame Shift Ins 2, 3'UTR 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 29/186 reads (16%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- A1CF | c.1306C>T p.P436S (on ENST00000373993 / NM_138932.2; = p.P428S on NM_014576.4) | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV50957440, COSV50964844; called by muse, mutect2, varscan2
- AAAS | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM055898, CM065946, COSV52932932; called by muse, mutect2, varscan2
- AASS | c.2522G>A p.S841N | Missense Mutation (SNP) | VAF 296/935 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV62789962; called by muse, mutect2, varscan2
- ABCA13 | c.9313C>A p.H3105N | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV101446961; called by muse, mutect2, varscan2
- ABCC3 | c.1536G>T p.K512N | Missense Mutation (SNP) | VAF 96/260 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as COSV53321473; called by muse, mutect2, varscan2
- ABCC4 | c.3316A>G p.T1106A | Missense Mutation (SNP) | VAF 71/293 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs776055053, COSV65312543; called by muse, mutect2, varscan2
- ABCF3 | c.1268A>G p.Q423R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV53052526; called by muse, mutect2, varscan2
- ACE | c.1488-2A>G p.X496_splice | Splice Site (SNP) | VAF 20/62 reads (32%) | catalogued as COSV52006673; called by muse, varscan2
- ACSBG1 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs935476084, COSV51905886; called by muse, mutect2, varscan2
- ADAMTS12 | c.4732C>A p.H1578N | Missense Mutation (SNP) | VAF 80/870 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV61262733; called by muse, mutect2
- ADGRF3 | c.1254del p.I419Sfs*42 (on ENST00000311519 / NM_001145168.1; = p.I220Sfs*42 on NM_153835.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | catalogued as COSV100275239; called by mutect2, pindel, varscan2
- ADGRL4 | c.397-2A>C p.X133_splice | Splice Site (SNP) | VAF 4/19 reads (21%) | catalogued as COSV66061579; called by muse, mutect2, varscan2
- ADRA1B | c.826A>G p.R276G | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV60701689; called by muse, mutect2, varscan2
- AGFG1 | c.1286C>G p.A429G | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV59511830; called by muse, mutect2
- AKAP4 | c.2090T>G p.I697R | Missense Mutation (SNP) | VAF 10/275 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV62074397; called by muse, mutect2
- AKAP6 | c.4354G>A p.D1452N | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.198); catalogued as rs1437896092, COSV55213495; called by muse, mutect2, varscan2
- ANKFN1 | c.2233G>T p.G745W | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100593498; called by muse, mutect2
- ANKRD46 | c.636+1G>A p.X212_splice (on ENST00000520552 / NM_001270379.2; = p.V213M on NM_198401.4) | Splice Site (SNP) | VAF 31/197 reads (16%) | catalogued as COSV59514390; called by muse, mutect2, varscan2
- ARFGEF2 | c.4375G>A p.G1459R | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64212230; called by muse, mutect2
- ARFGEF2 | c.4376G>T p.G1459V | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV64212232; called by muse, mutect2
- ARID4A | c.1391T>G p.L464* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV62163649; called by muse, mutect2
- AVL9 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333957429, COSV59465594; called by muse, mutect2, varscan2
- C2orf78 | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV68517507; called by muse, mutect2, varscan2
- C5orf22 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV57598408; called by muse, mutect2, varscan2
- C6orf58 | c.227C>A p.A76E | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV61666509; called by muse, mutect2, varscan2
- CA6 | c.532A>G p.S178G | Missense Mutation (SNP) | VAF 46/351 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV66262146; called by muse, mutect2, varscan2
- CACNA1C | c.6212C>A p.P2071H (on ENST00000399634 / NM_001167625.1; = p.P2000H on NM_000719.7) | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV59717004; called by mutect2, varscan2
- CCDC27 | c.1658T>C p.L553P | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV53900122; called by muse, mutect2, varscan2
- CD1D | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV63808985; called by muse, mutect2
- CDH10 | c.231+1G>T p.X77_splice | Splice Site (SNP) | VAF 127/274 reads (46%) | catalogued as COSV52580404; called by muse, varscan2
- CDH10 | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 129/281 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV52580410, COSV52598251; called by muse, varscan2
- CDK19 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 23/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60449254; called by muse, mutect2
- CEP135 | c.2797C>G p.Q933E | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.438); catalogued as COSV57259960, COSV57260710; called by muse, mutect2
- CFAP47 | c.4776G>T p.K1592N | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV57973774, COSV57976978; called by muse, mutect2, varscan2
- CFHR5 | c.1345T>C p.C449R | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56821855; called by muse, mutect2
- CHIT1 | c.749G>A p.W250* | Nonsense Mutation (SNP) | VAF 26/99 reads (26%) | catalogued as COSV55146846; called by muse, mutect2, varscan2
- CHRM2 | c.759T>A p.D253E | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV57771971; called by muse, mutect2, varscan2
- CHST1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV57323554; called by muse, mutect2, varscan2
- CLCN3 | c.1927G>T p.D643Y | Missense Mutation (SNP) | VAF 40/307 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV61627038; called by muse, mutect2, varscan2
- CLTCL1 | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54230393; called by muse, mutect2, varscan2
- CNKSR1 | c.1389T>G p.D463E (on ENST00000374253 / NM_001297647.2; = p.D456E on NM_006314.3) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs369423789; called by muse, mutect2, varscan2
- COL4A5 | c.394G>T p.G132* | Nonsense Mutation (SNP) | VAF 70/702 reads (10%) | catalogued as COSV60361322; called by muse, mutect2, varscan2
- COL4A5 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 72/714 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60361329; called by muse, mutect2, varscan2
- CRNKL1 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV55628870; called by muse, mutect2, varscan2
- CSF2RA | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 24/101 reads (24%) | catalogued as rs1316466248, COSV62624552; called by muse, mutect2, varscan2
- CSMD1 | c.8967G>A p.M2989I (on ENST00000520002; = p.M2988I on NM_033225.6) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as rs749027559, COSV59322288; called by muse, mutect2, varscan2
- CSMD2 | c.1979G>T p.S660I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV53911030; called by muse, mutect2, varscan2
- CSTF2 | c.193C>G p.Q65E | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV63376254; called by muse, mutect2, varscan2
- CTNNA3 | c.1978G>T p.A660S | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.994); catalogued as COSV65524420; called by muse, mutect2, varscan2
- CYFIP2 | c.3034G>C p.E1012Q (on ENST00000616178 / NM_001291722.2; = p.E987Q on NM_014376.4) | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV59036927; called by muse, mutect2, varscan2
- DCPS | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs140993180; called by muse, mutect2, varscan2
- DNAH11 | c.1186A>C p.I396L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV60955234; called by muse, mutect2, varscan2
- DOCK3 | c.1545G>T p.K515N | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56520925, COSV56521954; called by muse, mutect2
- DPP4 | c.360C>A p.Y120* | Nonsense Mutation (SNP) | VAF 85/265 reads (32%) | catalogued as COSV62106666; called by muse, mutect2, varscan2
- DSP | c.8426C>T p.S2809L | Missense Mutation (SNP) | VAF 24/431 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1355303627, COSV60940674; called by muse, mutect2
- DYTN | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 109/464 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.417); catalogued as COSV71752029; called by muse, mutect2, varscan2
- EDNRB | c.1243G>A p.V415I (on ENST00000377211 / NM_001201397.1; = p.V325I on NM_000115.5) | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs201437745, COSV57519503; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EEF1A1 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100303272, COSV104396981, COSV58549624; called by muse, mutect2, varscan2
- EFNB1 | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV52661659; called by muse, mutect2, varscan2
- EFNB2 | c.826A>T p.K276* | Nonsense Mutation (SNP) | VAF 53/187 reads (28%) | catalogued as COSV55364714; called by muse, mutect2, varscan2
- EIF2AK4 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 25/447 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs767768823, COSV55468240; called by muse, mutect2
- EPRS1 | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 76/403 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV65098819; called by muse, mutect2, varscan2
- EPRS1 | c.1914C>G p.D638E | Missense Mutation (SNP) | VAF 58/295 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.521); catalogued as COSV65098825; called by muse, mutect2, varscan2
- EPRS1 | c.631C>A p.H211N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV65098832; called by muse, mutect2, varscan2
- ERICH3 | c.2025A>T p.K675N | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV58606411; called by muse, mutect2, varscan2
- ETV3 | c.285-1G>T p.X95_splice | Splice Site (SNP) | VAF 65/224 reads (29%) | catalogued as COSV58748027; called by muse, mutect2, varscan2
- FAT1 | c.6373G>T p.E2125* | Nonsense Mutation (SNP) | VAF 101/263 reads (38%) | catalogued as COSV71673518; called by muse, mutect2, varscan2
- FBXW12 | c.391T>C p.W131R | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56483775; called by muse, mutect2, varscan2
- FBXW7 | c.1963G>T p.E655* (on ENST00000281708 / NM_001349798.2; = p.E575* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 84/190 reads (44%) | catalogued as COSV55900957; called by muse, mutect2, varscan2
- FER1L6 | c.2166G>T p.W722C | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV67549799; called by muse, mutect2, varscan2
- FER1L6 | c.2678A>C p.E893A | Missense Mutation (SNP) | VAF 152/574 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.222); catalogued as COSV67549801; called by muse, mutect2, varscan2
- FEZ1 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54028539; called by muse, mutect2, varscan2
- FIGN | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV60766502; called by muse, mutect2, varscan2
- FLG | c.1010G>C p.R337T | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.771); catalogued as rs1459896816; called by muse, mutect2
- FSHR | c.419A>T p.K140M | Missense Mutation (SNP) | VAF 75/362 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV58623293; called by muse, mutect2, varscan2
- GAB4 | c.1649A>G p.Q550R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs754860854, COSV68753815; called by muse, mutect2, varscan2
- GABRG1 | c.1387C>A p.L463I | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV54953887; called by muse, mutect2, varscan2
- GAR1 | c.623G>T p.R208I | Missense Mutation (SNP) | VAF 144/395 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV56993320; called by muse, varscan2
- GDAP1L1 | c.661C>A p.H221N | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV61157128; called by muse, mutect2, varscan2
- GDPD2 | c.1198C>G p.R400G | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV65531859; called by muse, mutect2, varscan2
- GLA | c.910A>T p.S304C | Missense Mutation (SNP) | VAF 64/673 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV54509103; called by muse, mutect2
- GOT2 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV55331573; called by muse, mutect2, varscan2
- GRM5 | c.799C>G p.H267D | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV59604507, COSV59631601; called by muse, mutect2, varscan2
- GRM8 | c.746A>T p.Q249L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as COSV100281313, COSV58825043; called by muse, mutect2, varscan2
- GUCY2F | c.3268G>T p.E1090* | Nonsense Mutation (SNP) | VAF 88/645 reads (14%) | catalogued as COSV54301725; called by muse, mutect2, varscan2
- HCAR1 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.09); catalogued as COSV63674351; called by muse, mutect2, varscan2
- HDC | c.1639G>C p.D547H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); catalogued as COSV51070172, COSV99984316; called by muse, mutect2, varscan2
- HERC2 | c.13948C>T p.R4650W | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762466850, COSV55322614; called by muse, mutect2, varscan2
- HERC6 | c.2632G>C p.G878R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52030000; called by muse, mutect2, varscan2
- HNRNPF | c.919A>T p.N307Y | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV61560984; called by muse, mutect2, varscan2
- HNRNPF | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61560992; called by muse, mutect2, varscan2
- HNRNPU | c.1927C>T p.P643S (on ENST00000283179; = p.P705S on NM_004501.3) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.565); catalogued as rs746093508, COSV51691071; called by mutect2, varscan2
- HNRNPUL1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 22/423 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV54562220; called by muse, mutect2
- ITIH5 | c.1816C>A p.Q606K | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0.192); catalogued as COSV53663951; called by muse, mutect2, varscan2
- ITM2A | c.268T>A p.C90S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV64810967; called by muse, mutect2, varscan2
- JUP | c.2225A>G p.H742R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV100159521, COSV60277976; called by muse, mutect2, varscan2
- KATNIP | c.1810T>G p.L604V | Missense Mutation (SNP) | VAF 147/663 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55180234; called by muse, mutect2, varscan2
- KCNJ2 | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM035531, CM053931, COSV54661694, COSV54664370; called by muse, mutect2, varscan2
- KLHL1 | c.1699C>A p.L567M | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1400777488, COSV64772177; called by muse, mutect2
- KNDC1 | c.1813G>T p.V605L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.838); catalogued as rs1314233654, COSV58836772; called by muse, mutect2, varscan2
- KRT31 | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV52435063; called by muse, mutect2, varscan2
- KRT6B | c.603G>T p.Q201H | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV52882762, COSV99360741; called by muse, mutect2
- LARGE1 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV61661650; called by muse, mutect2, varscan2
- LARP4B | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.159); catalogued as rs1336227133, COSV60221416; called by muse, mutect2, varscan2
- LRRC15 | c.1703G>T p.S568I | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV61650073; called by muse, mutect2
- LRRC27 | c.1461A>C p.L487F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as COSV63997050; called by muse, mutect2
- MACF1 | c.8830C>G p.Q2944E | Missense Mutation (SNP) | VAF 17/180 reads (9%) | catalogued as COSV57111556; called by muse, mutect2
- MAP2 | c.379G>C p.A127P | Missense Mutation (SNP) | VAF 116/420 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.914); catalogued as COSV52290510; called by muse, mutect2, varscan2
- MAPT | c.2272G>A p.G758R (on ENST00000262410 / NM_001377265.1; = p.G366R on NM_005910.5) | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs948573449, CM121237, COSV52240278; called by muse, mutect2, varscan2
- MDM1 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as COSV57445924; called by muse, mutect2, varscan2
- MDN1 | c.14036G>C p.G4679A | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65521424; called by muse, mutect2
- MPDZ | c.5881G>T p.A1961S (on ENST00000319217 / NM_001330637.2; = p.A1932S on NM_003829.5) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV59917796; called by muse, mutect2, varscan2
- MRGPRX1 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 169/1042 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV57107251; called by muse, mutect2, varscan2
- MUC16 | c.25309C>A p.L8437I | Missense Mutation (SNP) | VAF 136/345 reads (39%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.549); catalogued as COSV67460274, COSV67464951; called by muse, mutect2, varscan2
- MUC16 | c.7432A>G p.M2478V | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV67464961; called by muse, mutect2, varscan2
- MYH6 | c.5284A>C p.T1762P | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62450294; called by muse, mutect2, varscan2
- MYO10 | c.3623G>T p.R1208L | Missense Mutation (SNP) | VAF 154/278 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs939141866, COSV57016606, COSV57021340; called by muse, varscan2
- MYO10 | c.3622C>T p.R1208C | Missense Mutation (SNP) | VAF 158/290 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762663185, COSV57021366; called by muse, varscan2
- MYO1H | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.95); catalogued as rs1566044250, COSV60445611; called by muse, mutect2, varscan2
- NAP1L3 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.283); catalogued as COSV100220523, COSV59075231; called by muse, mutect2, varscan2
- NCOA2 | c.3244C>T p.Q1082* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV51219318; called by muse, mutect2, varscan2
- NCSTN | c.435T>C p.F145= | Splice Region (SNP) | VAF 83/208 reads (40%) | catalogued as COSV54187559; called by muse, mutect2, varscan2
- NDUFA9 | c.731A>T p.D244V | Missense Mutation (SNP) | VAF 92/250 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56929204, COSV56931173; called by muse, mutect2, varscan2
- NELFA | c.1540G>A p.D514N (on ENST00000542778; = p.D503N on NM_005663.5) | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1426626443, COSV56390532; called by muse, mutect2, varscan2
- NKRF | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV58661575; called by muse, varscan2
- NLRP12 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV60747251; called by muse, mutect2, varscan2
- NLRP13 | c.2151C>A p.S717R | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV61621631; called by muse, mutect2, varscan2
- NNT | c.1271G>C p.R424T | Missense Mutation (SNP) | VAF 200/333 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV52924912; called by muse, mutect2, varscan2
- NOX4 | c.725A>T p.Y242F | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV54452980; called by muse, mutect2, varscan2
- NSMCE1 | c.125A>G p.K42R | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs937153015, COSV63864277; called by muse, mutect2
- NXPH1 | c.114C>A p.S38R | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV68314553; called by muse, mutect2, varscan2
- OR4P4 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV58921130, COSV58921916; called by muse, mutect2, varscan2
- OR52A5 | c.127G>T p.G43* | Nonsense Mutation (SNP) | VAF 31/174 reads (18%) | catalogued as COSV56615031, COSV56615221; called by muse, mutect2, varscan2
- OR5A1 | c.199A>C p.S67R | Missense Mutation (SNP) | VAF 48/572 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV57376667; called by muse, mutect2
- PAH | c.1154T>C p.L385P | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV61014139, COSV61016359; called by muse, mutect2
- PCDHGA10 | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.029); catalogued as rs749121255, COSV53945509; called by muse, mutect2
- PDCD11 | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 61/317 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV63933944; called by muse, mutect2, varscan2
- PEA15 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 104/843 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1329677839, COSV58783696; called by muse, mutect2, varscan2
- PHACTR1 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.258); catalogued as COSV60666355; called by muse, mutect2, varscan2
- PHOX2A | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53355478; called by muse, mutect2, varscan2
- PI4KA | c.2564C>T p.T855M | Missense Mutation (SNP) | VAF 61/622 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55410734; called by muse, mutect2
- PIK3C2A | c.3477C>G p.I1159M | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.875); catalogued as COSV56402686; called by muse, mutect2, varscan2
- PNISR | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65079434; called by muse, mutect2, varscan2
- POU2F1 | c.464C>G p.A155G (on ENST00000541643 / NM_001365848.1; = p.A178G on NM_002697.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54816916; called by muse, mutect2, varscan2
- PROM1 | c.1276A>G p.T426A | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.036); catalogued as rs760172617, COSV71699420; called by muse, mutect2, varscan2
- PSMA8 | c.253A>G p.T85A | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs1217621677, COSV57602414; called by muse, mutect2, varscan2
- PTH2R | c.1034G>T p.W345L | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.944); catalogued as rs151296979; called by muse, mutect2, varscan2
- PTPRT | c.3224del p.P1075Rfs*6 | Frame Shift Del (DEL) | VAF 24/67 reads (36%) | catalogued as rs1568940954, COSV62005004; called by mutect2, pindel, varscan2
- PTPRZ1 | c.4367T>A p.M1456K | Missense Mutation (SNP) | VAF 88/216 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV66436244; called by muse, mutect2, varscan2
- RASGRP3 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371456335, COSV67820308; called by muse, mutect2, varscan2
- SEC24C | c.885T>A p.N295K | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.09); catalogued as COSV59541772; called by muse, mutect2, varscan2
- SELP | c.2114C>A p.S705* | Nonsense Mutation (SNP) | VAF 39/173 reads (23%) | catalogued as COSV55251853; called by muse, mutect2, varscan2
- SEPTIN12 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51617026; called by muse, mutect2, varscan2
- SEPTIN12 | c.167-1G>T p.X56_splice | Splice Site (SNP) | VAF 15/47 reads (32%) | catalogued as COSV51617038; called by muse, mutect2, varscan2
- SERPINB13 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 47/222 reads (21%) | catalogued as COSV54028533; called by muse, mutect2, varscan2
- SIM1 | c.892C>G p.L298V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53491994; called by muse, mutect2, varscan2
- SLC16A6 | c.1055A>T p.N352I | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV59177326; called by muse, mutect2, varscan2
- SLC2A13 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs1269189401, COSV55117325; called by muse, mutect2, varscan2
- SLC37A1 | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as rs538286192; called by muse, mutect2, varscan2
- SLC8B1 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 42/1674 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1314816341, COSV52527786; called by muse, mutect2
- SMYD3 | c.820G>A p.D274N (on ENST00000490107 / NM_001375962.1; = p.D215N on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.149); catalogued as COSV63626872; called by muse, mutect2
- SPAM1 | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56143537, COSV56147120; called by muse, mutect2, varscan2
- ST8SIA2 | c.168A>T p.E56D | Missense Mutation (SNP) | VAF 43/307 reads (14%) | PolyPhen benign (0.3); catalogued as COSV51569350; called by muse, mutect2, varscan2
- TAF1L | c.3644G>A p.R1215H | Missense Mutation (SNP) | VAF 68/527 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs757557186, COSV54258123; called by muse, mutect2, varscan2
- TAF1L | c.3433C>T p.R1145W | Missense Mutation (SNP) | VAF 101/216 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs767903653, COSV54261702; called by muse, mutect2, varscan2
- TENT4A | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50095560; called by muse, mutect2
- TIGD6 | c.1343C>A p.A448E | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.145); catalogued as COSV57060958; called by muse, mutect2, varscan2
- TMEM181 | c.1219G>T p.V407L | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV65563137; called by muse, mutect2, varscan2
- TMEM186 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs926224066, COSV51631734, COSV51632856; called by muse, mutect2, varscan2
- TP53 | c.672G>C p.E224D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as CS100446, COSV52678333, COSV52681634, COSV52721244; called by muse, mutect2, varscan2
- TTC27 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV58651563; called by muse, mutect2
- TTN | c.96589G>C p.E32197Q (on ENST00000591111; = p.E24773Q on NM_003319.4) | Missense Mutation (SNP) | VAF 40/343 reads (12%) | PolyPhen probably damaging (0.998); catalogued as COSV60049660; called by muse, mutect2, varscan2
- TTN | c.85637T>C p.I28546T (on ENST00000591111; = p.I21122T on NM_003319.4) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | PolyPhen benign (0.005); catalogued as COSV60049736; called by muse, mutect2, varscan2
- UPF3B | c.373C>A p.Q125K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.45); catalogued as COSV52229992, COSV52231789; called by muse, mutect2
- UQCR10 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs749721393; called by muse, mutect2, varscan2
- USP49 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV51896950, COSV99790207; called by muse, mutect2
- WNT9B | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV51518405; called by muse, mutect2
- WWP2 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63124901; called by muse, mutect2, varscan2
- ZBBX | c.2213A>T p.Q738L | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56789028; called by muse, mutect2, varscan2
- ZNF236 | c.2918A>G p.N973S | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV53488053; called by muse, mutect2, varscan2
- ZNF518B | c.2289G>T p.K763N | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.123); catalogued as COSV58721718, COSV58722557; called by muse, mutect2, varscan2
- ZNF527 | c.50G>T p.R17I | Missense Mutation (SNP) | VAF 63/293 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV62230494; called by muse, mutect2, varscan2
- ZNF91 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 13/155 reads (8%) | catalogued as COSV56080497, COSV56084325; called by muse, mutect2
- ABCC2 | c.2996G>A p.W999* | Nonsense Mutation (SNP) | VAF 40/323 reads (12%) | called by muse, mutect2, varscan2
- CHRDL1 | c.1223-2A>G p.X408_splice (on ENST00000372045; = p.X414_splice on NM_145234.4) | Splice Site (SNP) | VAF 14/287 reads (5%) | called by muse, mutect2
- CTDSP2 | c.719dup p.M240Ifs*5 | Frame Shift Ins (INS) | VAF 20/85 reads (24%) | called by mutect2, pindel, varscan2
- DNAJC13 | c.4221_4227del p.D1408Sfs*16 | Frame Shift Del (DEL) | VAF 16/170 reads (9%) | called by mutect2, pindel
- EIF3K | c.364del p.D122Mfs*10 | Frame Shift Del (DEL) | VAF 20/235 reads (9%) | called by mutect2, pindel
- FAT1 | c.3206_3214delinsG p.I1069Sfs*3 | Frame Shift Del (DEL) | VAF 27/229 reads (12%) | called by pindel, varscan2*
- FNDC7 | c.959T>C p.V320A | Missense Mutation (SNP) | VAF 24/504 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- FREM1 | c.2247C>A p.F749L | Missense Mutation (SNP) | VAF 35/524 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); called by muse, mutect2
- GDF3 | c.124del p.Q42Rfs*10 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | called by mutect2, pindel, varscan2
- HLA-E | c.790_799del p.K264Lfs*27 | Frame Shift Del (DEL) | VAF 11/84 reads (13%) | called by mutect2, varscan2
- IGKV3D-11 | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA10 | c.3435G>A p.W1145* | Nonsense Mutation (SNP) | VAF 17/257 reads (7%) | called by muse, mutect2
- ITGA10 | c.3434G>A p.W1145* | Nonsense Mutation (SNP) | VAF 18/261 reads (7%) | called by muse, mutect2
- MAP3K1 | c.1145A>G p.N382S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- MAVS | c.338C>A p.P113H | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, varscan2
- MTMR1 | c.1330del p.R444Efs*11 | Frame Shift Del (DEL) | VAF 44/432 reads (10%) | called by mutect2, pindel, varscan2
- NBPF15 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 156/639 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- NET1 | c.958T>G p.L320V (on ENST00000355029 / NM_001047160.3; = p.L266V on NM_005863.5) | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PCDHAC2 | c.1850del p.N617Mfs*8 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, varscan2
- PHLPP2 | c.3731C>T p.S1244F | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- POM121C | c.2653C>A p.P885T (on ENST00000607367; = p.P643T on NM_001099415.3) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- PRAMEF18 | c.864C>A p.I288= | Splice Region (SNP) | VAF 41/243 reads (17%) | called by muse, mutect2, varscan2
- PSMD5 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 19/278 reads (7%) | called by muse, mutect2
- RBP3 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- SALL4 | c.1412_1415del p.S471* | Frame Shift Del (DEL) | VAF 21/152 reads (14%) | called by pindel, varscan2
- SH3D19 | c.1874T>A p.V625E | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TTN | c.96970C>T p.Q32324* (on ENST00000591111; = p.Q24900* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2
- UACA | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 35/413 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- ZBTB5 | c.1673C>A p.T558N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0); called by mutect2, varscan2
- ABCC10 | c.2247C>T p.L749= (on ENST00000372530 / NM_001198934.2; = p.L721= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as rs763453216, COSV55087618; called by muse, mutect2, varscan2
- ADGRB2 | c.4374C>A p.S1458= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV57073562, COSV57078222; called by muse, mutect2, varscan2
- AFF2 | c.1674G>C p.L558= | Silent (SNP) | VAF 80/658 reads (12%) | catalogued as COSV53984000; called by muse, mutect2, varscan2
- AMER1 | c.3189T>C p.S1063= | Silent (SNP) | VAF 5/32 reads (16%) | called by mutect2, varscan2
- ANKRD30A | c.543G>C p.T181= (on ENST00000611781; = p.T125= on NM_052997.2) | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV64609214, COSV64609913; called by muse, mutect2, varscan2
- ARHGAP20 | c.2301C>T p.V767= | Silent (SNP) | VAF 7/143 reads (5%) | catalogued as rs1407241943; called by muse, mutect2
- BAZ1B | c.2305A>C p.R769= | Silent (SNP) | VAF 27/233 reads (12%) | catalogued as COSV59991026; called by muse, mutect2, varscan2
- CBX5 | c.75G>T p.V25= | Silent (SNP) | VAF 9/291 reads (3%) | called by muse, mutect2
- CCDC50 | c.696G>A p.R232= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV101165289; called by muse, mutect2, varscan2
- CDC27 | c.903C>T p.Y301= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV50383669, COSV50643098; called by muse, mutect2, varscan2
- CELSR2 | c.8373A>T p.P2791= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV54771529; called by muse, mutect2, varscan2
- CEP164 | c.2778T>C p.D926= | Silent (SNP) | VAF 110/614 reads (18%) | catalogued as COSV54041096; called by muse, mutect2, varscan2
- COL4A6 | c.1071C>A p.I357= | Silent (SNP) | VAF 20/378 reads (5%) | catalogued as COSV57863075; called by muse, mutect2
- CST11 | c.153C>A p.I51= | Silent (SNP) | VAF 96/986 reads (10%) | catalogued as COSV63140115; called by muse, mutect2
- CYP7A1 | c.384T>A p.T128= | Silent (SNP) | VAF 57/200 reads (29%) | catalogued as COSV56963472; called by muse, mutect2, varscan2
- DOCK6 | c.594A>C p.A198= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV53914679; called by muse, mutect2
- EFNB1 | c.216C>T p.P72= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV52661669; called by muse, mutect2, varscan2
- EPHB3 | c.1227G>T p.R409= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV57805857; called by muse, mutect2, varscan2
- FBXO27 | c.813G>A p.V271= | Silent (SNP) | VAF 35/188 reads (19%) | catalogued as COSV53072370; called by muse, mutect2, varscan2
- FLG | c.10188T>A p.S3396= | Silent (SNP) | VAF 68/447 reads (15%) | catalogued as COSV64241676, COSV64247628; called by muse, mutect2, varscan2
- GRIA3 | c.2094G>T p.V698= | Silent (SNP) | VAF 38/261 reads (15%) | catalogued as COSV52059045; called by muse, mutect2, varscan2
- IGHV1-46 | c.216T>A p.P72= | Silent (SNP) | VAF 14/370 reads (4%) | catalogued as rs540499178; called by muse, mutect2
- IGHV1OR15-9 | c.33G>C p.V11= | Silent (SNP) | VAF 73/235 reads (31%) | catalogued as rs759530603; called by muse, mutect2, varscan2
- KCNK9 | c.726C>T p.V242= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs113907649; called by muse, mutect2, varscan2
- KIAA1210 | c.4566C>A p.S1522= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV68177137, COSV68179007; called by muse, varscan2
- KIAA1549L | c.5154C>A p.A1718= (on ENST00000321505; = p.A2015= on NM_012194.3) | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV58588356; called by muse, mutect2, varscan2
- KIF18B | c.360G>T p.L120= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV100192190; called by muse, mutect2, varscan2
- LAS1L | c.2061C>T p.P687= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV56707276; called by muse, mutect2, varscan2
- LGI1 | c.135G>A p.V45= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV65057983; called by muse, mutect2, varscan2
- MAP3K21 | c.912A>T p.T304= | Silent (SNP) | VAF 100/249 reads (40%) | catalogued as COSV64043163, COSV64044602; called by muse, mutect2, varscan2
- MFN1 | c.1398C>T p.N466= | Silent (SNP) | VAF 14/159 reads (9%) | catalogued as rs369815541; called by muse, mutect2
- MFSD5 | c.267C>A p.V89= | Silent (SNP) | VAF 65/487 reads (13%) | catalogued as COSV61565524; called by muse, mutect2, varscan2
- MYLK | c.2115C>T p.R705= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as rs774165971; called by muse, mutect2, varscan2
- MYO6 | c.576T>C p.F192= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as COSV64118929; called by muse, mutect2, varscan2
- MYPN | c.2664G>A p.G888= | Silent (SNP) | VAF 20/161 reads (12%) | catalogued as rs1351171087, COSV62731580, COSV62733840; called by muse, mutect2, varscan2
- NOS1 | c.1506C>A p.A502= | Silent (SNP) | VAF 38/137 reads (28%) | catalogued as COSV57612107; called by muse, mutect2, varscan2
- OIT3 | c.1296G>A p.L432= | Silent (SNP) | VAF 29/195 reads (15%) | catalogued as COSV61826046, COSV61826672; called by muse, mutect2, varscan2
- OR4C46 | c.597C>G p.A199= | Silent (SNP) | VAF 41/201 reads (20%) | catalogued as COSV60219302; called by muse, mutect2
- OR6C1 | c.792T>C p.D264= | Silent (SNP) | VAF 35/204 reads (17%) | catalogued as rs748579568, COSV65573371; called by muse, mutect2, varscan2
- OTOGL | c.2268G>A p.S756= (on ENST00000547103; = p.S747= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as rs1036677659, COSV101509275; called by muse, mutect2, varscan2
- PBRM1 | c.1782C>T p.F594= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV56275776; called by muse, mutect2
- PCDHGA10 | c.2250T>G p.V750= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs777503392, COSV53945497; called by muse, mutect2
- PGK2 | c.132C>T p.I44= | Silent (SNP) | VAF 63/272 reads (23%) | catalogued as COSV59163816; called by muse, mutect2, varscan2
- PLEKHA6 | c.783G>T p.G261= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs751835630, COSV55333582; called by muse, mutect2, varscan2
- POLA1 | c.1803C>G p.V601= | Silent (SNP) | VAF 27/152 reads (18%) | catalogued as COSV66886145; called by muse, mutect2, varscan2
- POLR1F | c.801G>C p.A267= | Silent (SNP) | VAF 247/1306 reads (19%) | catalogued as COSV55997996, COSV55998463; called by muse, mutect2, varscan2
- PRR23B | c.222C>T p.D74= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV61493268, COSV61493598; called by muse, mutect2
- RFX7 | c.3501A>G p.A1167= (on ENST00000559447 / NM_001368074.1; = p.A1264= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV57963265; called by muse, mutect2, varscan2
- SLC17A6 | c.324C>G p.G108= | Silent (SNP) | VAF 28/136 reads (21%) | catalogued as COSV54136298; called by muse, mutect2, varscan2
- SLC6A19 | c.690C>G p.P230= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV58671177; called by muse, mutect2, varscan2
- SYT13 | c.906C>T p.N302= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as rs779255449, COSV50073607; called by muse, mutect2, varscan2
- TAS2R50 | c.327G>A p.K109= | Silent (SNP) | VAF 14/430 reads (3%) | called by muse, mutect2
- TTN | c.91282T>C p.L30428= (on ENST00000591111; = p.L23004= on NM_003319.4) | Silent (SNP) | VAF 89/382 reads (23%) | catalogued as rs770663539, COSV60049689; called by muse, mutect2, varscan2
- TUBA3C | c.27G>T p.V9= | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as COSV67139274; called by muse, mutect2, varscan2
- VMA21 | c.294C>A p.G98= | Silent (SNP) | VAF 9/239 reads (4%) | catalogued as COSV57756569; called by muse, mutect2
- WBP4 | c.276A>G p.P92= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV65273916; called by muse, mutect2, varscan2
- ZFHX4 | c.9348C>A p.S3116= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV50780425; called by muse, mutect2, varscan2
- ZIC1 | c.408C>T p.D136= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV51550748, COSV51553019; called by mutect2, varscan2
- AGAP7P | n.1208C>A | RNA (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- ANKRD33 | c.664+38G>A | Intron (SNP) | VAF 8/23 reads (35%) | catalogued as rs371567187, COSV100001051; called by muse, mutect2, varscan2
- DPP6 | c.627+21114G>T | Intron (SNP) | VAF 39/378 reads (10%) | catalogued as COSV100125684; called by muse, varscan2
- DST | c.4297-3919C>T | Intron (SNP) | VAF 32/98 reads (33%) | catalogued as COSV99755773, COSV99756095; called by muse, mutect2, varscan2
- HTN1 | c.-2C>A | 5'UTR (SNP) | VAF 7/120 reads (6%) | catalogued as COSV99887521; called by muse, mutect2
- MAPK10 | c.*11G>A | 3'UTR (SNP) | VAF 36/322 reads (11%) | called by muse, mutect2
- MAPK10 | c.*9G>A | 3'UTR (SNP) | VAF 38/328 reads (12%) | catalogued as COSV60378269; called by muse, mutect2
- MELTF | c.712+1660del | Intron (DEL) | VAF 6/64 reads (9%) | called by mutect2, varscan2
- PANK2 | c.1536+455G>C | Intron (SNP) | VAF 16/327 reads (5%) | catalogued as COSV57254249; called by muse, mutect2
- PDE4B | c.281+74194A>C | Intron (SNP) | VAF 31/129 reads (24%) | catalogued as rs116785815, COSV100303632; called by muse, mutect2, varscan2
- PKD1L2 | n.723G>A | RNA (SNP) | VAF 73/217 reads (34%) | catalogued as rs962181647; called by muse, mutect2, varscan2
- SLIT3 | c.198-12197C>T | Intron (SNP) | VAF 9/25 reads (36%) | catalogued as rs528719712, COSV60607601; called by muse, mutect2, varscan2
- SNORD116-2 | n.89G>C | RNA (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+1598C>T | Intron (SNP) | VAF 40/114 reads (35%) | catalogued as COSV100314277; called by muse, mutect2, varscan2
- TMEM99 | n.842C>G | RNA (SNP) | VAF 55/409 reads (13%) | catalogued as rs774061894, COSV56982950; called by muse, mutect2, varscan2
- TTN | c.10361-3802C>G | Intron (SNP) | VAF 60/214 reads (28%) | catalogued as COSV60049780; called by muse, mutect2, varscan2
- UBE2D3 | c.398+478G>T | Intron (SNP) | VAF 137/406 reads (34%) | catalogued as COSV100414924; called by muse, mutect2, varscan2
